Surgical pathology report (de-identified scan), TCGA case TCGA-D8-A1JN, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D8-A1JN-01A (Primary Tumor).

[page 1 of 2]
1CD-0-3

Carcinoma, infiltrating lobular, NOS 8520/3

Site: breast, NOS C50.9 3/11/11 *ju*

page 1 / 2

Department of Cancer Pathology

copy No.

Date:

Examination: Histopathological examination

Examination No.:

Patient: [REDACTED] PESEL: [REDACTED] Age: Gender: F

Material: Multiple organ resection – left breast

Unit in charge:

Physician in charge:

Material collected on:

Material received on:

Expected time of examination: up to 8 working days

Clinical diagnosis:

Examination performed on:

Results of immunohistochemical examination:

Estrogen receptors found in 75% of neoplastic cell nuclei. Progesterone receptors found in 10% of neoplastic cell nuclei. HER2 protein stained with HercepTest™ by DAKO.

Score = 2+, verification by the FISH method recommended.

Compliance validated by:

Examination performed on:

Macroscopic description:

Left breast sized 17.8 x 11.3 x 4.8 cm removed with axillary tissues sized 9 x 5 x 3 cm. Weight 400 g. Skin flap 21.7 x 9.2 cm in size. Tumour sized 3.9 x 6.6 x 2.8 cm found in the central part, placed 1.4 cm from the upper edge, 0.9 cm from the base and 0.0 cm from the skin.

Status after biopsy (test No.:

Microscopic description:

Carcinoma lobulare invasivum (G2 acc. to Elston: 3+2+1; 0 mitoses /10 HPF diam. 0.55 mm) infiltratio carcinomatosa cutis et mamillae. Glandular tissue showing parenchyma atrophy.

Invasive lesions are placed 0.1 cm from the base of the surgical specimen. Axillary lymph nodes: Metastases carcinomatosa in lymphonodo (No XI / XIII).

Histopathological diagnosis:

(Including test No.

Ca rei nom alobulare invasivum mammae sinistrae. Invasive lobular carcinoma of the left breast

Metastases carcinomatosa in lymphonodis axillae (XI / XIII) Cancer metastases in axillary lymph nodes (XI/XIII) (NHG2, pT3, pN3a).

Compliance validated by:

Dual Synchronisation Primary Record		☒
Casey Circumstances		☒

[page 2 of 2]
Examination performed on:

Examination: Histopathological examination page 2 / 2

Examination No.:

Patient: [REDACTED] PESEL: [REDACTED] Gender: F

Examination performed on:

Results of immunohistochemical examination:

RESULT OF HER2/neu GENE AMPLIFICATION with the FISH method by Path Vysion HER2 DNA Probe Kit

FINAL RESULT:

HER-2 GENE AMPLIFICATION NOT FOUND

Compliance validated by:

Source: NCI Genomic Data Commons file c96b66bf-2c51-4e44-b1df-8792625a53f2 (TCGA-D8-A1JN.021DF0B3-A535-4AD4-9545-1B9A7BC3E1E6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).